Somatic mutation profile of tumor specimen ALCH-B3GJ-TTP1-A (aliquot ALCH-B3GJ-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3GJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 63.2 years (23,093 days).
Specimen ALCH-B3GJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39274b6f-42f6-4e01-95cc-7b1a25e41063.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GJ-NB1-A (Blood Derived Normal), aliquot ALCH-B3GJ-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/103c8a83-9b1f-4b9f-a447-eda88f8495aa

The open-access MAF lists 2,230 somatic variants for this specimen: 1,517 protein-altering or splice-affecting, 417 silent, 296 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,298, Silent 417, Intron 122, Nonsense Mutation 83, RNA 57, 3'UTR 51, Frame Shift Del 51, Splice Site 44, 5'UTR 28, 5'Flank 25, Splice Region 20, 3'Flank 13.

Variants (750 of 2,230; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4175C>A p.S1392* | Nonsense Mutation (SNP) | VAF 79/140 reads (56%) | catalogued as rs786204170, CM960068, CM990162, COSV57326586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876661151; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIM1 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 135/164 reads (82%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs377274719, COSV65165126; called by muse, mutect2, varscan2
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 51/76 reads (67%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, varscan2
- ABCA5 | c.4765G>T p.A1589S | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs910917944; called by muse, varscan2
- ABCB4 | c.2518G>T p.A840S | Missense Mutation (SNP) | VAF 90/589 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs771776079; called by muse, mutect2, varscan2
- ACKR1 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as COSV100929676; called by muse, mutect2, varscan2
- ACTBL2 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 117/165 reads (71%) | catalogued as rs1254578408; called by muse, mutect2, varscan2
- ADAM18 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 99/171 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as COSV55851511; called by muse, mutect2, varscan2
- ADAMTS12 | c.4174G>T p.V1392L | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV100711434, COSV61275688; called by muse, mutect2, varscan2
- ADAMTS3 | c.1641G>T p.Q547H | Missense Mutation (SNP) | VAF 70/296 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV54406356; called by muse, mutect2, varscan2
- ADAMTS5 | c.1503C>A p.F501L | Missense Mutation (SNP) | VAF 36/385 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs770985728, COSV99537673; called by muse, mutect2
- ADAMTSL1 | c.4778C>T p.A1593V | Missense Mutation (SNP) | VAF 110/189 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.312); catalogued as COSV65878388; called by muse, mutect2, varscan2
- ADCY2 | c.2192C>A p.A731E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57871248; called by muse, mutect2, varscan2
- AFF2 | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 72/92 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV53990957; called by muse, mutect2, varscan2
- AFF2 | c.1937C>A p.P646H | Missense Mutation (SNP) | VAF 152/202 reads (75%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.797); catalogued as COSV99667215; called by muse, mutect2, varscan2
- AFF2 | c.3155C>A p.S1052Y | Missense Mutation (SNP) | VAF 82/108 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53998879; called by muse, mutect2, varscan2
- AGRN | c.4483G>T p.V1495L | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs781321119; called by muse, mutect2, varscan2
- ALPK3 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs755344188; called by muse, mutect2, varscan2
- ALX4 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV61325298; called by muse, mutect2, varscan2
- ANK3 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs981773418; called by muse, mutect2, varscan2
- ANKRD18B | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1425022351; called by muse, mutect2, varscan2
- ANKRD30A | c.3467C>A p.S1156* (on ENST00000611781; = p.S1100* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 93/271 reads (34%) | catalogued as COSV64614463, COSV64624230; called by muse, mutect2, varscan2
- ANKRD30A | c.3625C>G p.H1209D (on ENST00000611781; = p.H1153D on NM_052997.2) | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV64607243, COSV64609821; called by muse, mutect2, varscan2
- ANKRD36C | c.3335C>T p.T1112I | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1418512617; called by muse, mutect2, varscan2
- ANKRD63 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 95/138 reads (69%) | SIFT tolerated (0.11); catalogued as COSV53045562; called by muse, mutect2, varscan2
- ANXA1 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV57411218; called by muse, mutect2, varscan2
- AP2A2 | c.2053G>C p.V685L | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.872); catalogued as rs776924402, COSV59965552; called by muse, mutect2, varscan2
- APMAP | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV54173631; called by mutect2, varscan2
- ARF5 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.606); catalogued as rs767496095; called by muse, mutect2, varscan2
- ARHGAP15 | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV54514650; called by muse, mutect2, varscan2
- ARMC4 | c.1370T>G p.L457R | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53468655; called by muse, mutect2, varscan2
- ARMH4 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 140/244 reads (57%) | catalogued as COSV50769740; called by muse, mutect2, varscan2
- ASAP2 | c.198G>T p.L66= | Splice Region (SNP) | VAF 51/368 reads (14%) | catalogued as COSV55638348; called by muse, mutect2, varscan2
- ASCL1 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57151894; called by muse, mutect2, varscan2
- ASH1L | c.5950C>T p.P1984S | Missense Mutation (SNP) | VAF 142/277 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs761759606; called by muse, mutect2, varscan2
- ASTN1 | c.2135G>T p.C712F | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56060746; called by muse, mutect2, varscan2
- ATF7IP2 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 153/219 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0.176); catalogued as rs1256143736; called by muse, mutect2, varscan2
- ATN1 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 30/615 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63112383; called by muse, mutect2
- ATP8B4 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52713142, COSV52715223; called by muse, mutect2, varscan2
- BCL2L13 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100456377; called by muse, mutect2, varscan2
- BICRAL | c.2267T>C p.F756S | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58404603; called by muse, mutect2, varscan2
- BMERB1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 131/176 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV55509054; called by muse, mutect2, varscan2
- BPI | c.1078C>A p.Q360K (on ENST00000262865; = p.Q356K on NM_001725.3) | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs769550438; called by muse, mutect2, varscan2
- BPIFB2 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV50067681; called by muse, mutect2, varscan2
- BSND | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 71/98 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100987607; called by muse, mutect2, varscan2
- BTBD9 | c.859G>C p.V287L | Missense Mutation (SNP) | VAF 281/487 reads (58%) | SIFT tolerated (0.8); PolyPhen benign (0.089); catalogued as COSV58431994; called by muse, mutect2, varscan2
- BTD | c.-293+5G>T | Splice Region (SNP) | VAF 56/156 reads (36%) | catalogued as rs1204599121; called by muse, mutect2, varscan2
- C12orf75 | c.30C>A p.S10R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1348599334; called by muse, mutect2, varscan2
- C6orf163 | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV66361845; called by muse, mutect2, varscan2
- CACNA1C | c.5581G>A p.G1861S | Missense Mutation (SNP) | VAF 122/258 reads (47%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); catalogued as rs777107907; called by muse, mutect2, varscan2
- CACNA1E | c.6592C>A p.Q2198K (on ENST00000367573 / NM_001205293.3; = p.Q2155K on NM_000721.4) | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs559196607, COSV100701348, COSV62433984; called by muse, mutect2, varscan2
- CALB1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs750409917; called by muse, mutect2, varscan2
- CARD6 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99620639; called by muse, mutect2, varscan2
- CASR | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as CM055919, CM124154; called by muse, mutect2, varscan2
- CATSPER1 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1363608134; called by muse, mutect2, varscan2
- CCDC141 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575572900; called by mutect2, varscan2
- CCDC144A | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 34/371 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.267); catalogued as rs750175196, COSV60701277; called by muse, mutect2, varscan2
- CCDC168 | c.9474G>T p.K3158N | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1398033699; called by muse, mutect2, varscan2
- CCDC33 | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs1339014293; called by muse, mutect2, varscan2
- CCDC38 | c.399del p.K135Sfs*6 | Frame Shift Del (DEL) | VAF 51/144 reads (35%) | catalogued as COSV100717553; called by mutect2, pindel, varscan2
- CCDC39 | c.1615T>C p.F539L | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as rs1333998142; called by muse, mutect2, varscan2
- CCDC60 | c.527T>C p.M176T | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1178141200; called by muse, mutect2, varscan2
- CCDC7 | c.3217G>C p.G1073R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100178655; called by muse, mutect2, varscan2
- CD163L1 | c.4230G>C p.E1410D | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs1565774282, COSV58013505; called by muse, mutect2, varscan2
- CD163L1 | c.3569G>T p.G1190V | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58015276; called by muse, mutect2, varscan2
- CD22 | c.1423G>T p.V475F | Missense Mutation (SNP) | VAF 148/346 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV50068396; called by muse, mutect2, varscan2
- CD248 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV60937727; called by muse, mutect2, varscan2
- CD300LG | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 32/41 reads (78%) | catalogued as rs1387891856, COSV53224748; called by muse, mutect2, varscan2
- CD8A | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.405); catalogued as rs1161733294; called by muse, varscan2
- CD96 | c.752T>C p.V251A (on ENST00000283285 / NM_198196.3; = p.V235A on NM_005816.5) | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV51912164; called by muse, mutect2, varscan2
- CDC42BPG | c.4012G>T p.D1338Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61346273; called by muse, mutect2, varscan2
- CDC5L | c.1811G>T p.G604V | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs773228211; called by muse, mutect2, varscan2
- CDH10 | c.1811T>A p.L604H | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.919); catalogued as rs1159512565; called by muse, mutect2, varscan2
- CDH10 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV52589943; called by muse, varscan2
- CDH10 | c.1091C>A p.P364Q | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV100051697; called by muse, varscan2
- CDH11 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs769244467, COSV51756574; called by muse, mutect2, varscan2
- CDH18 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 33/234 reads (14%) | catalogued as COSV56923749; called by muse, mutect2, varscan2
- CDH18 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56923309; called by muse, mutect2, varscan2
- CEP126 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs1236193836; called by muse, mutect2, varscan2
- CEP164 | c.3485G>C p.R1162P | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV104378782; called by muse, mutect2, varscan2
- CEP290 | c.2644A>G p.N882D | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs1389791714; called by muse, mutect2, varscan2
- CERCAM | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs139025492, COSV65710836; called by muse, mutect2, varscan2
- CFAP52 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 99/143 reads (69%) | catalogued as COSV55346863; called by muse, mutect2, varscan2
- CFAP54 | c.8164A>G p.N2722D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as rs764137236; called by muse, mutect2
- CFAP58 | c.1600T>A p.S534T | Missense Mutation (SNP) | VAF 67/193 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.02); catalogued as rs1344499976; called by muse, mutect2, varscan2
- CHMP4B | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV99459760; called by muse, varscan2
- CHPF | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60536126; called by muse, mutect2, varscan2
- CIB2 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51949410; called by muse, mutect2, varscan2
- CLDN14 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1323556417; called by muse, mutect2, varscan2
- CLEC14A | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as COSV60563149; called by muse, mutect2, varscan2
- CLEC18B | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 65/688 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs747304170; called by muse, mutect2, varscan2
- CLHC1 | c.1282A>G p.S428G | Missense Mutation (SNP) | VAF 176/558 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs778020485; called by muse, mutect2, varscan2
- CMKLR1 | c.886C>A p.L296M (on ENST00000312143 / NM_001142344.2; = p.L294M on NM_004072.3) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56436594; called by muse, mutect2, varscan2
- CNBD2 | c.1401_1403del p.M467del (on ENST00000373973 / NM_001365709.1; = p.M463del on NM_080834.4) | In Frame Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs1285110628; called by pindel, varscan2
- CNGA1 | c.1846C>G p.P616A | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV62053680; called by muse, mutect2, varscan2
- CNGB1 | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 120/399 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV51904209; called by muse, mutect2, varscan2
- CNTNAP5 | c.3107C>G p.S1036C | Missense Mutation (SNP) | VAF 322/613 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV70478224; called by muse, mutect2, varscan2
- COL11A1 | c.1068G>T p.E356D | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.899); catalogued as COSV62199290; called by muse, mutect2, varscan2
- COL15A1 | c.1490G>C p.R497P | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100898092; called by muse, mutect2, varscan2
- COL1A2 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201137000; called by muse, mutect2, varscan2
- COL2A1 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 136/321 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61529119; called by muse, mutect2, varscan2
- COL4A5 | c.3338G>C p.G1113A | Missense Mutation (SNP) | VAF 246/320 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs957082431; called by muse, mutect2, varscan2
- COL4A5 | c.4600G>T p.D1534Y | Missense Mutation (SNP) | VAF 170/219 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1033301411; called by muse, mutect2, varscan2
- COL6A3 | c.5369C>T p.A1790V | Missense Mutation (SNP) | VAF 92/159 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs140513454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A3 | c.369C>A p.P123= | Splice Region (SNP) | VAF 104/287 reads (36%) | catalogued as COSV59650304; called by muse, varscan2
- CPED1 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100121143; called by muse, mutect2, varscan2
- CPVL | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV55307828; called by muse, mutect2, varscan2
- CRB2 | c.1742A>G p.Q581R | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1377557720; called by muse, mutect2, varscan2
- CSNK1A1L | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 159/271 reads (59%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.978); catalogued as rs376452704, COSV65789870; called by muse, mutect2, varscan2
- CTCF | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 107/344 reads (31%) | catalogued as COSV50519222; called by muse, mutect2, varscan2
- CUX2 | c.2513C>A p.A838E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.308); catalogued as rs557884358, COSV55626928; called by muse, mutect2, varscan2
- DAGLB | c.2003G>A p.S668N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs375537082; called by muse, mutect2
- DCAF15 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54330226; called by muse, mutect2, varscan2
- DCAF16 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV66384092; called by muse, mutect2, varscan2
- DCAF4L2 | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100150386, COSV60477329; called by muse, mutect2, varscan2
- DCBLD1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs563062366; called by muse, mutect2, varscan2
- DCLRE1C | c.458G>T p.G153V (on ENST00000378278 / NM_001350965.2; = p.G38V on NM_022487.4) | Missense Mutation (SNP) | VAF 143/503 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63182715; called by muse, mutect2, varscan2
- DDX31 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547453630; called by muse, mutect2, varscan2
- DHX9 | c.518A>T p.H173L | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62361245; called by muse, mutect2, varscan2
- DLL3 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs1045208902; called by muse, mutect2, varscan2
- DNAH14 | c.4548G>T p.K1516N (on ENST00000445597; = p.K1921N on NM_001367479.1) | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as COSV60736720; called by muse, mutect2, varscan2
- DPP4 | c.118C>A p.R40S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.152); catalogued as COSV62105981; called by muse, mutect2, varscan2
- DPP6 | c.967G>T p.V323F (on ENST00000377770 / NM_001364500.2; = p.V261F on NM_001936.5) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221318463; called by muse, varscan2
- DSG2 | c.2444del p.S815Ifs*7 | Frame Shift Del (DEL) | VAF 156/334 reads (47%) | catalogued as COSV55198088; called by mutect2, pindel, varscan2
- DZIP1L | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs764902342; called by muse, mutect2, varscan2
- EDN3 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100285094, COSV100285140; called by muse, mutect2, varscan2
- EFCAB3 | c.461C>A p.P154H | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs760554924; called by muse, mutect2, varscan2
- EHMT2 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 73/85 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs748231118; called by muse, mutect2, varscan2
- EIF2S3B | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 104/332 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100483577; called by muse, mutect2, varscan2
- ENPP2 | c.1932C>A p.S644R (on ENST00000075322 / NM_001040092.3; = p.S696R on NM_006209.5) | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs566612458, COSV50027990; called by muse, mutect2, varscan2
- EP300 | c.1913A>G p.Y638C | Missense Mutation (SNP) | VAF 103/158 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376635222; called by muse, mutect2, varscan2
- ERV3-1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); catalogued as rs745713493; called by muse, mutect2, varscan2
- EVX2 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 151/417 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as rs1379226242, COSV57962786; called by muse, mutect2, varscan2
- EXOC3 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.604); catalogued as rs777484890; called by muse, mutect2, varscan2
- EYS | c.3535C>A p.H1179N | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.132); catalogued as rs1382164059, COSV100426406; called by muse, mutect2, varscan2
- FAIM2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV57738189; called by muse, mutect2, varscan2
- FAM135B | c.1622C>A p.P541Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.388); catalogued as COSV52724942; called by muse, mutect2, varscan2
- FAM135B | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1270251100; called by muse, mutect2, varscan2
- FAM163B | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV100618902; called by muse, mutect2, varscan2
- FAM71E2 | c.2594C>A p.P865H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58484492; called by muse, mutect2, varscan2
- FAM78B | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57975467; called by muse, mutect2, varscan2
- FANCA | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 259/762 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as rs142620413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAR2 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99478754; called by muse, mutect2, varscan2
- FAT3 | c.4705C>A p.P1569T | Missense Mutation (SNP) | VAF 128/509 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99962055; called by muse, mutect2, varscan2
- FAT4 | c.9608del p.P3203Lfs*16 | Frame Shift Del (DEL) | VAF 37/183 reads (20%) | catalogued as COSV58707830; called by mutect2, pindel, varscan2
- FBN2 | c.4708G>T p.G1570C | Missense Mutation (SNP) | VAF 160/294 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554121027; called by muse, mutect2, varscan2
- FBN2 | c.3998C>A p.S1333* | Nonsense Mutation (SNP) | VAF 90/187 reads (48%) | catalogued as rs1189153876; called by muse, mutect2, varscan2
- FBXL18 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV101212103; called by muse, mutect2, varscan2
- FBXL7 | c.1463C>G p.P488R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100310402, COSV61654403; called by muse, mutect2, varscan2
- FGD5 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs755052596; called by muse, mutect2, varscan2
- FLNC | c.2893G>T p.D965Y | Missense Mutation (SNP) | VAF 171/434 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57960113; called by muse, mutect2, varscan2
- FLT3 | c.1306A>T p.R436* | Nonsense Mutation (SNP) | VAF 70/176 reads (40%) | catalogued as COSV54056623; called by muse, mutect2, varscan2
- FOXA1 | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 114/165 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0.07); catalogued as COSV99163222; called by muse, mutect2, varscan2
- FOXI3 | c.985A>T p.S329C | Missense Mutation (SNP) | VAF 140/399 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV101230958; called by muse, mutect2, varscan2
- FRMPD1 | c.1766C>A p.A589E | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs574623304; called by muse, mutect2, varscan2
- FSIP2 | c.16505G>T p.G5502V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV104420869; called by muse, mutect2, varscan2
- FZD1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 138/267 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55309837; called by muse, mutect2, varscan2
- FZD3 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 128/225 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460432566; called by muse, mutect2, varscan2
- GALNT13 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67209831; called by muse, mutect2, varscan2
- GALNT17 | c.1163G>T p.S388I | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.397); catalogued as COSV61163320; called by muse, mutect2, varscan2
- GBP4 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 89/119 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs75750014, COSV63254858; called by muse, mutect2, varscan2
- GLT1D1 | c.733G>A p.V245M (on ENST00000442111 / NM_001366889.1; = p.V165M on NM_144669.3) | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs778043963; called by muse, mutect2, varscan2
- GLYAT | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs757762637; called by muse, mutect2, varscan2
- GP5 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs975298609; called by muse, mutect2, varscan2
- GPAT2 | c.1131C>A p.H377Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs760066050; called by muse, mutect2, varscan2
- GPATCH8 | c.2241G>T p.R747S | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1043832034, COSV100132686; called by muse, mutect2, varscan2
- GPM6A | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 155/293 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs758808847; called by muse, mutect2, varscan2
- GPR141 | c.472C>G p.H158D | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV57732138; called by muse, mutect2, varscan2
- GPR162 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs781975870, COSV50591407; called by muse, mutect2, varscan2
- GPR26 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV52932330; called by muse, mutect2, varscan2
- GPRIN3 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201061407; called by mutect2, varscan2
- GPX1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1250568793; called by muse, mutect2, varscan2
- GRIN2A | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 130/188 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV58050670; called by muse, mutect2, varscan2
- GRIP2 | c.991G>A p.V331M (on ENST00000619221; = p.V234M on NM_001080423.4) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56123345; called by muse, mutect2, varscan2
- GRIP2 | c.693C>T p.P231= (on ENST00000619221; = p.P134= on NM_001080423.4) | Splice Region (SNP) | VAF 45/92 reads (49%) | catalogued as rs372338980, COSV56119454; called by muse, mutect2, varscan2
- GRM5 | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 72/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59634957; called by muse, mutect2, varscan2
- GTF2E1 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV52206533; called by muse, mutect2, varscan2
- HCN1 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV57512187; called by muse, mutect2, varscan2
- HCN4 | c.1796C>A p.A599E | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56083280; called by muse, mutect2, varscan2
- HEPH | c.1190G>T p.G397V (on ENST00000343002; = p.G130V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/88 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1453495458; called by muse, mutect2, varscan2
- HMCN1 | c.1545C>G p.D515E | Missense Mutation (SNP) | VAF 137/470 reads (29%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.929); catalogued as COSV54894142; called by muse, mutect2, varscan2
- HRNR | c.6435G>T p.R2145S | Missense Mutation (SNP) | VAF 221/4484 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100914020, COSV64257174; called by muse, mutect2
- HSPBP1 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as rs1213168104; called by muse, mutect2, varscan2
- HSPBP1 | c.640+1G>T p.X214_splice | Splice Site (SNP) | VAF 34/72 reads (47%) | catalogued as rs1278618213; called by muse, mutect2
- HTR1B | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64051364; called by muse, mutect2, varscan2
- HTR3E | c.1126C>A p.P376T (on ENST00000415389 / NM_001256613.1; = p.P391T on NM_182589.2) | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs750368531; called by muse, mutect2, varscan2
- HTRA3 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs765049863, COSV56471190; called by muse, mutect2, varscan2
- HYDIN | c.8184C>A p.N2728K | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs749067771; called by mutect2, varscan2
- IDH3A | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 131/398 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.744); catalogued as COSV51908659; called by muse, mutect2, varscan2
- IGHV2-70 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371486752; called by muse, mutect2, varscan2
- IGLV4-60 | c.230del p.Y77Sfs*? | Frame Shift Del (DEL) | VAF 48/140 reads (34%) | catalogued as COSV66503442; called by mutect2, pindel*, varscan2
- IGSF1 | c.2533G>T p.G845W | Missense Mutation (SNP) | VAF 144/178 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812071; called by muse, mutect2, varscan2
- IKBIP | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1409016426; called by muse, mutect2, varscan2
- IL18RAP | c.922A>C p.I308L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51827085; called by muse, mutect2, varscan2
- IL1R1 | c.130T>C p.C44R | Missense Mutation (SNP) | VAF 95/352 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1198478724; called by muse, mutect2, varscan2
- IRS2 | c.3907G>A p.G1303S | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs1174414481, COSV65480585; called by muse, mutect2, varscan2
- ITGAE | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1372804550; called by muse, mutect2, varscan2
- JAKMIP1 | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs756950973, COSV51535318; called by muse, mutect2, varscan2
- JCAD | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 106/325 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64759757; called by muse, mutect2, varscan2
- KCNG3 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs769021571; called by muse, mutect2, varscan2
- KCNH5 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 110/134 reads (82%) | SIFT tolerated (0.15); PolyPhen benign (0.348); catalogued as rs1162818997; ClinVar: uncertain significance; called by muse, varscan2
- KCNK12 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV59946037; called by muse, mutect2, varscan2
- KERA | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.058); catalogued as rs751660260; called by muse, mutect2, varscan2
- KIAA1586 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV66056580; called by muse, mutect2, varscan2
- KIDINS220 | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876483; called by muse, mutect2, varscan2
- KIF26A | c.1679C>G p.A560G | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as rs371178408; called by muse, mutect2, varscan2
- KL | c.2632G>A p.G878R | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.242); catalogued as rs199676672, COSV66309227; called by muse, mutect2, varscan2
- KLRC2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 75/280 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67900606; called by muse, mutect2, varscan2
- KREMEN2 | c.466T>A p.C156S | Missense Mutation (SNP) | VAF 88/113 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs1193886199; called by muse, mutect2, varscan2
- KRTAP13-1 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 85/138 reads (62%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV62664367; called by muse, mutect2, varscan2
- KRTAP24-1 | c.40del p.V14Sfs*15 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | catalogued as COSV61089039; called by mutect2, pindel, varscan2
- LAMB3 | c.1830G>T p.W610C | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as CM981170; called by muse, mutect2, varscan2
- LAMC3 | c.3673G>T p.V1225L | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62654553; called by muse, mutect2, varscan2
- LELP1 | c.93C>G p.C31W | Missense Mutation (SNP) | VAF 252/548 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs748663720, COSV100907342; called by muse, mutect2, varscan2
- LMNA | c.1969-1G>T p.X657_splice | Splice Site (SNP) | VAF 120/493 reads (24%) | catalogued as rs1060499873, COSV61543321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPO | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV51858854; called by muse, mutect2, varscan2
- LPP | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV57091820; called by muse, mutect2, varscan2
- LRIF1 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 145/377 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1221462433, COSV63898430; called by muse, mutect2, varscan2
- LRIT1 | c.1418G>T p.R473L | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV100927977; called by muse, mutect2, varscan2
- LRRC1 | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63823143; called by muse, mutect2, varscan2
- LRRIQ1 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101279809; called by muse, mutect2, varscan2
- LRRK2 | c.3417C>A p.N1139K | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779085159; called by muse, mutect2, varscan2
- LYAR | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs79312020, COSV58643912; called by muse, varscan2
- MAB21L2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV58263504; called by muse, mutect2, varscan2
- MAG | c.1722G>T p.E574D | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV62699040; called by muse, mutect2, varscan2
- MAGEB6B | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 123/159 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.102); catalogued as COSV69689734; called by muse, mutect2, varscan2
- MAP3K10 | c.900G>C p.E300D | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs948088861; called by muse, mutect2, varscan2
- MAPKBP1 | c.2276C>G p.P759R (on ENST00000456763 / NM_001128608.2; = p.P753R on NM_014994.3) | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV52958860; called by muse, mutect2, varscan2
- MCFD2 | c.127A>G p.K43E | Missense Mutation (SNP) | VAF 63/610 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs763902751; called by muse, mutect2, varscan2
- MEF2D | c.1022G>T p.S341I | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV61730139; called by muse, mutect2, varscan2
- METTL18 | c.931A>T p.R311* | Nonsense Mutation (SNP) | VAF 90/175 reads (51%) | catalogued as rs1558032170; called by muse, mutect2, varscan2
- METTL8 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs545647826, COSV64549204; called by muse, mutect2, varscan2
- MMP1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 36/125 reads (29%) | catalogued as COSV59510812; called by muse, mutect2, varscan2
- MMP10 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54245599, COSV54247289; called by muse, mutect2, varscan2
- MPP6 | c.424-1G>A p.X142_splice | Splice Site (SNP) | VAF 4/35 reads (11%) | catalogued as COSV56038480; called by muse, mutect2, varscan2
- MRGPRF | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs918732602; called by muse, mutect2, varscan2
- MROH5 | c.1187C>G p.P396R | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71302334; called by muse, mutect2, varscan2
- MS4A5 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 111/267 reads (42%) | catalogued as COSV55741540; called by muse, mutect2, varscan2
- MSGN1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1004595252, COSV55264005; called by muse, mutect2, varscan2
- MTIF2 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV55051562; called by muse, mutect2, varscan2
- MUC1 | c.3413G>T p.R1138L (on ENST00000611571 / NM_001371720.1; = p.R149L on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs770482054; called by muse, mutect2, varscan2
- MUC12 | c.953C>A p.T318K (on ENST00000379442; = p.T175K on NM_001164462.1) | Missense Mutation (SNP) | VAF 108/392 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs769176549, COSV65182189; called by muse, mutect2, varscan2
- MUC15 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 114/173 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55554836; called by muse, mutect2, varscan2
- MUC16 | c.15118C>A p.P5040T | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as COSV99064286; called by muse, mutect2, varscan2
- MUC17 | c.2666C>G p.P889R | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV60298538; called by muse, mutect2, varscan2
- MYF6 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 56/167 reads (34%) | catalogued as COSV57353771; called by muse, mutect2, varscan2
- MYH7B | c.2776G>A p.V926I | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs755719619; called by muse, mutect2, varscan2
- MYO15A | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV52760337; called by muse, mutect2, varscan2
- MYO16 | c.4490C>A p.P1497Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62748889; called by muse, mutect2, varscan2
- MYO18B | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs532925728, COSV59147003; called by muse, mutect2, varscan2
- MYO3A | c.3370G>C p.D1124H | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as COSV99779972; called by muse, mutect2, varscan2
- MYO7B | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs1163860817; called by muse, mutect2, varscan2
- MYO7B | c.4214C>G p.P1405R | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762488567, COSV101267907; called by muse, mutect2, varscan2
- MYO9B | c.4043C>T p.T1348I | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1190989619; called by muse, mutect2, varscan2
- MYO9B | c.4382G>T p.G1461V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as COSV68279474; called by muse, mutect2, varscan2
- MYPN | c.3599C>A p.P1200Q | Missense Mutation (SNP) | VAF 144/335 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as rs767967746, COSV99081839; called by muse, mutect2, varscan2
- NCOA7 | c.2402G>T p.G801V | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57653302; called by muse, mutect2, varscan2
- NDUFAF5 | c.863-2A>G p.X288_splice | Splice Site (SNP) | VAF 66/192 reads (34%) | catalogued as COSV100961961; called by muse, mutect2, varscan2
- NEB | c.13486A>G p.K4496E | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1489496024; called by muse, mutect2, varscan2
- NES | c.4006G>C p.V1336L | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs570678384; called by muse, mutect2, varscan2
- NETO1 | c.209A>T p.Y70F | Missense Mutation (SNP) | VAF 106/204 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV55013004; called by muse, mutect2, varscan2
- NEUROD4 | c.263del p.R88Qfs*16 | Frame Shift Del (DEL) | VAF 85/253 reads (34%) | catalogued as COSV99669698; called by mutect2, pindel, varscan2
- NF1 | c.5273G>C p.G1758A (on ENST00000358273 / NM_001042492.3; = p.G1737A on NM_000267.3) | Missense Mutation (SNP) | VAF 201/303 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1358882546, COSV62228087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP3 | c.1546T>C p.Y516H | Missense Mutation (SNP) | VAF 127/174 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1558192160; called by muse, mutect2, varscan2
- NOBOX | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99779870; called by mutect2, varscan2
- NOS1 | c.1801C>T p.R601C | Missense Mutation (SNP) | VAF 138/335 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1231111386, COSV57606543; called by muse, mutect2, varscan2
- NPAP1 | c.1034T>A p.L345Q | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT tolerated (0.46); PolyPhen benign (0.422); catalogued as rs764547724; called by muse, mutect2, varscan2
- NR4A2 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 141/428 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59892822; called by muse, mutect2, varscan2
- NRXN1 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV68021127; called by muse, mutect2, varscan2
- NT5DC3 | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1237710666, COSV67321698; called by muse, mutect2, varscan2
- NUP210L | c.2154C>G p.I718M | Missense Mutation (SNP) | VAF 105/388 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.467); catalogued as COSV55157527; called by muse, mutect2, varscan2
- NUP214 | c.6177G>C p.Q2059H | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1396581015; called by muse, mutect2, varscan2
- NYAP1 | c.2268G>T p.Q756H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55720318; called by muse, mutect2, varscan2
- OPRPN | c.440C>A p.T147N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); catalogued as COSV68192550; called by muse, mutect2, varscan2
- OR10H3 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 68/171 reads (40%) | catalogued as COSV59944450; called by muse, mutect2, varscan2
- OR10K2 | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 197/370 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs771087443; called by muse, mutect2, varscan2
- OR11H2 | c.424G>T p.G142W (on ENST00000556246; = p.G153W on NM_001197287.1) | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs771353050; called by muse, mutect2, varscan2
- OR1N2 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101031392; called by muse, mutect2, varscan2
- OR2F2 | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV68833151; called by muse, mutect2, varscan2
- OR2G3 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 80/114 reads (70%) | catalogued as rs1480706476, COSV60683437; called by muse, varscan2
- OR2L3 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63455742, COSV63456116; called by muse, mutect2, varscan2
- OR2L8 | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100594030, COSV61727789; called by muse, varscan2
- OR4A5 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV60524598; called by muse, mutect2, varscan2
- OR4D11 | c.671C>G p.T224R | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV57585431; called by muse, mutect2, varscan2
- OR51T1 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 110/199 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1302874120, COSV59027303; called by muse, mutect2, varscan2
- OR52A5 | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 77/122 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1368325389; called by muse, mutect2, varscan2
- OR52N1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 99/186 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs756095593; called by muse, mutect2, varscan2
- OR5AP2 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1473714468; called by muse, mutect2, varscan2
- OR5T2 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs879438417, COSV100507113; called by muse, mutect2, varscan2
- OR8B8 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.566); catalogued as rs777775770, COSV100045241; called by muse, mutect2, varscan2
- OR8K5 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147115733; called by muse, mutect2, varscan2
- OR8K5 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV57888620; called by muse, mutect2, varscan2
- OR9G1 | c.230C>A p.T77N | Missense Mutation (SNP) | VAF 74/511 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs765054948; called by muse, mutect2, varscan2
- OR9K2 | c.838G>T p.V280F (on ENST00000305377; = p.V258F on NM_001005243.1) | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV59531261; called by muse, mutect2, varscan2
- OTOG | c.4974A>T p.R1658S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV61128712; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1126G>C p.V376L (on ENST00000259318 / NM_001136562.3; = p.V607L on NM_007203.5) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99394975; called by muse, mutect2, varscan2
- PAPPA2 | c.1678C>A p.R560S | Missense Mutation (SNP) | VAF 92/417 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV100866390, COSV62776538; called by muse, mutect2, varscan2
- PARP1 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs140136106, COSV64691429; called by muse, mutect2, varscan2
- PAX1 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68271395; called by mutect2, varscan2
- PAX1 | c.414del p.Q139Sfs*9 | Frame Shift Del (DEL) | VAF 50/194 reads (26%) | catalogued as COSV68272760; called by mutect2, pindel, varscan2
- PCDH19 | c.2372G>T p.R791L (on ENST00000373034 / NM_001184880.2; = p.R744L on NM_020766.3) | Missense Mutation (SNP) | VAF 116/154 reads (75%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV55266763; called by muse, mutect2, varscan2
- PCDHA12 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 201/324 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56553142; called by muse, mutect2, varscan2
- PCDHA8 | c.1928C>A p.P643Q | Missense Mutation (SNP) | VAF 90/151 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.433); catalogued as COSV65330060; called by muse, mutect2, varscan2
- PCDHB2 | c.2054C>A p.A685D | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV50577011; called by muse, mutect2
- PCDHB4 | c.1642G>T p.V548L | Missense Mutation (SNP) | VAF 211/331 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs782717887, COSV99521738; called by muse, mutect2, varscan2
- PCDHB9 | c.2048C>A p.A683D | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.394); catalogued as rs782583106, COSV53379359; called by muse, mutect2, varscan2
- PCDHGB1 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 56/80 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs539097472, COSV53988672; called by muse, mutect2, varscan2
- PCDHGB1 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs762118992; called by muse, mutect2, varscan2
- PCSK2 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99359504; called by muse, mutect2, varscan2
- PCSK2 | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99360164; called by muse, mutect2, varscan2
- PCSK5 | c.5276C>A p.A1759E | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101377290; called by muse, mutect2, varscan2
- PDE1C | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs148832869; called by muse, mutect2, varscan2
- PDE4D | c.290C>A p.S97* | Nonsense Mutation (SNP) | VAF 55/76 reads (72%) | catalogued as COSV61419632; called by muse, mutect2, varscan2
- PDE4D | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 98/135 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as rs1211297841; called by muse, mutect2, varscan2
- PDE6B | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV55329017; called by muse, mutect2, varscan2
- PDPR | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 48/572 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as rs745370851; called by muse, mutect2
- PEG3 | c.4405G>T p.E1469* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | catalogued as COSV55647819; called by muse, mutect2, varscan2
- PEG3 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55629994; called by muse, varscan2
- PHOX2B | c.899G>C p.R300T | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV56930893; called by muse, mutect2, varscan2
- PIK3R4 | c.3761C>G p.P1254R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62030109; called by muse, mutect2, varscan2
- PIP5KL1 | c.1060G>T p.G354W (on ENST00000388747 / NM_001135219.2; = p.G151W on NM_173492.1) | Missense Mutation (SNP) | VAF 140/213 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769512742, COSV55944975; called by muse, mutect2, varscan2
- PKHD1 | c.8555G>T p.G2852V | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100580825; called by muse, mutect2, varscan2
- PLCB4 | c.3505C>G p.R1169G (on ENST00000278655 / NM_182797.3; = p.P1181R on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.043); catalogued as COSV53805537, COSV99597126; called by muse, mutect2, varscan2
- PLD1 | c.2084G>A p.R695H | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777216916; called by muse, mutect2, varscan2
- PLEKHA6 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55340192; called by muse, mutect2, varscan2
- PNLDC1 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 83/108 reads (77%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs778909851, COSV99277837; called by muse, mutect2, varscan2
- POU6F2 | c.953C>A p.S318* | Nonsense Mutation (SNP) | VAF 115/275 reads (42%) | catalogued as rs748605828; called by muse, mutect2, varscan2
- PPIP5K2 | c.2596A>G p.M866V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1554221444; called by muse, mutect2, varscan2
- PPM1A | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 139/229 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57788132; called by muse, mutect2, varscan2
- PPP1R3A | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 56/171 reads (33%) | catalogued as COSV52880562; called by muse, mutect2, varscan2
- PRAME | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1362387052; called by muse, mutect2, varscan2
- PRAMEF2 | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV99534831; called by muse, varscan2
- PRDM7 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 242/975 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1362407474; called by muse, mutect2, varscan2
- PRDM7 | c.1441C>A p.P481T | Missense Mutation (SNP) | VAF 247/979 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV57986083; called by muse, mutect2, varscan2
- PRDM9 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 58/422 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99691115; called by muse, mutect2, varscan2
- PRPF6 | c.854del p.G285Efs*43 | Frame Shift Del (DEL) | VAF 101/322 reads (31%) | catalogued as COSV53879245; called by mutect2, pindel, varscan2
- PRR5 | c.737A>G p.K246R (on ENST00000336985 / NM_181333.4; = p.K237R on NM_015366.4) | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as rs767279783; called by muse, mutect2, varscan2
- PSD | c.1441A>G p.R481G | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs1173337555; called by muse, mutect2, varscan2
- PSRC1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs201898139; called by muse, mutect2, varscan2
- PTF1A | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1209942756; called by muse, mutect2, varscan2
- PTGER3 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1012439042; called by muse, mutect2, varscan2
- PTPRQ | c.6825G>A p.M2275I (on ENST00000616559; = p.M2242I on NM_001145026.2) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1031264716; called by muse, mutect2, varscan2
- PXDNL | c.2834C>A p.A945E | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as rs1158594975, COSV62478104, COSV62493633; called by muse, mutect2
- QRFPR | c.539T>C p.M180T | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1171913966; called by muse, mutect2, varscan2
- R3HDM1 | c.2506A>C p.S836R | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV51528888; called by muse, mutect2, varscan2
- RAB1B | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 65/355 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs780097222, COSV61012253; called by muse, mutect2, varscan2
- RAB4B | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 90/181 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs200980353; called by muse, varscan2
- RAD18 | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV53749523; called by muse, mutect2, varscan2
- RASA3 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1308058052; called by muse, mutect2, varscan2
- RASAL1 | c.2381G>C p.R794P | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.147); catalogued as rs371604812; called by muse, mutect2, varscan2
- RET | c.3065C>T p.T1022I | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262202036; called by muse, mutect2, varscan2
- RFX6 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs752679591, COSV60588010; called by muse, mutect2, varscan2
- ROBO1 | c.4324A>T p.S1442C | Missense Mutation (SNP) | VAF 119/306 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV71393041, COSV71396093; called by muse, mutect2, varscan2
- ROBO2 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV59922831; called by muse, varscan2
- ROBO2 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 87/205 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM145975; called by muse, varscan2
- ROR2 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV65216127; called by muse, mutect2, varscan2
- RXFP2 | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs759827365, COSV100034797; called by muse, mutect2, varscan2
- RYR3 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs763701721, COSV101214079, COSV66803663; called by muse, mutect2, varscan2
- RYR3 | c.10204G>T p.D3402Y (on ENST00000389232; = p.D3403Y on NM_001036.6) | Missense Mutation (SNP) | VAF 87/144 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66787350, COSV66799653; called by muse, mutect2, varscan2
- S1PR1 | c.351G>C p.W117C | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59513076; called by muse, mutect2, varscan2
- SALL1 | c.2792del p.P931Rfs*35 | Frame Shift Del (DEL) | VAF 140/334 reads (42%) | catalogued as COSV51764357; called by mutect2, pindel, varscan2
- SAMD3 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV62384564; called by muse, mutect2
- SCN10A | c.3660G>C p.W1220C | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV71862203; called by muse, mutect2, varscan2
- SCN11A | c.2851C>T p.Q951* | Nonsense Mutation (SNP) | VAF 60/161 reads (37%) | catalogued as rs1553635777, COSV100182601; called by muse, mutect2, varscan2
- SDHAF1 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 172/344 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs777257006; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC24B | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as COSV54499257; called by muse, mutect2, varscan2
- SEC31A | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs771446934; called by muse, mutect2, varscan2
- SEMA5B | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 74/246 reads (30%) | catalogued as COSV52105761; called by muse, mutect2, varscan2
- SEMG2 | c.1618C>A p.H540N | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV65647427; called by muse, mutect2, varscan2
- SEPTIN14 | c.721-2A>G p.X241_splice | Splice Site (SNP) | VAF 47/202 reads (23%) | catalogued as rs376964833; called by muse, mutect2, varscan2
- SHROOM3 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV56023292; called by muse, mutect2, varscan2
- SI | c.2441T>A p.L814Q | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100016447; called by muse, mutect2, varscan2
- SIK3 | c.3251G>A p.R1084H (on ENST00000445177 / NM_001366686.2; = p.R1042H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs769627045; called by muse, mutect2, varscan2
- SKAP1 | c.179-1G>A p.X60_splice | Splice Site (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100411881; called by muse, mutect2, varscan2
- SKI | c.2183C>G p.P728R | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); catalogued as rs372950890; called by muse, mutect2, varscan2
- SLC16A6 | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0.268); catalogued as COSV59176080; called by muse, mutect2, varscan2
- SLC25A32 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM162833; called by muse, varscan2
- SLC2A12 | c.1087A>G p.I363V | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as rs376594692; called by muse, mutect2, varscan2
- SLC35F4 | c.760C>A p.P254T (on ENST00000339762 / NM_001352015.2; = p.P218T on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60266336; called by muse, mutect2, varscan2
- SLC52A1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 140/213 reads (66%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV54693266; called by muse, mutect2, varscan2
- SLC6A2 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV54913963; called by muse, mutect2, varscan2
- SLC8A1 | c.1452C>G p.I484M | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60491629; called by muse, mutect2, varscan2
- SLCO4C1 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60515390; called by muse, mutect2, varscan2
- SLITRK1 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV65676771; called by muse, mutect2, varscan2
- SLITRK6 | c.132G>T p.M44I | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV68392026; called by muse, mutect2, varscan2
- SMARCA4 | c.2617-1G>T p.X873_splice | Splice Site (SNP) | VAF 29/43 reads (67%) | catalogued as COSV60809901; called by muse, mutect2, varscan2
- SMPD3 | c.1138G>C p.G380R | Missense Mutation (SNP) | VAF 167/422 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV99546172; called by muse, mutect2, varscan2
- SNAP91 | c.1190A>T p.E397V | Missense Mutation (SNP) | VAF 99/204 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs1373212574; called by muse, mutect2, varscan2
- SORCS3 | c.1848G>T p.W616C | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs753357253, COSV63821990; called by muse, mutect2, varscan2
- SORL1 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV99495243, COSV99495683; called by muse, mutect2, varscan2
- SPDEF | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 106/150 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV99763240; called by muse, mutect2, varscan2
- SPECC1L | c.1606G>C p.A536P | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV58656373; called by muse, mutect2, varscan2
- SPEG | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs200437079; called by muse, mutect2, varscan2
- SPHKAP | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV60881758, COSV60891098; called by muse, mutect2, varscan2
- SPOCK3 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62715273; called by muse, mutect2, varscan2
- SSTR4 | c.748C>A p.R250S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV54798527; called by muse, mutect2, varscan2
- STK40 | c.113-4G>A | Splice Region (SNP) | VAF 100/137 reads (73%) | catalogued as rs368597188; called by muse, mutect2, varscan2
- STOML2 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 57/140 reads (41%) | catalogued as COSV58927357; called by muse, mutect2, varscan2
- STXBP5L | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56524645; called by muse, mutect2, varscan2
- STXBP5L | c.1554G>T p.Q518H | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV99875353; called by muse, mutect2, varscan2
- STXBP5L | c.3447G>C p.R1149S | Missense Mutation (SNP) | VAF 104/312 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1284302554; called by muse, mutect2, varscan2
- SYTL1 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 112/178 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58871283; called by muse, varscan2
- SZT2 | c.5896G>A p.V1966I (on ENST00000634258 / NM_001365999.1; = p.V1909I on NM_015284.4) | Missense Mutation (SNP) | VAF 185/252 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1297183193, COSV100986954; called by muse, mutect2, varscan2
- TADA2B | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.099); catalogued as rs772148070; called by muse, mutect2, varscan2
- TAF2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as COSV100978624; called by muse, mutect2, varscan2
- TANC2 | c.5651A>G p.N1884S | Missense Mutation (SNP) | VAF 78/140 reads (56%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1249139588; called by muse, mutect2, varscan2
- TANGO6 | c.1697A>G p.Q566R | Missense Mutation (SNP) | VAF 131/251 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1377003215; called by muse, mutect2, varscan2
- TAP1 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 97/375 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV62755364; called by muse, mutect2, varscan2
- TCAF2 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1247723878; called by muse, mutect2, varscan2
- TFAP2B | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs761528653, COSV53826979; called by muse, mutect2, varscan2
- TFAP2D | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs780379700, COSV50410964; called by muse, mutect2, varscan2
- THNSL2 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs1365614378, COSV59082668; called by muse, varscan2
- TIAM1 | c.4479T>A p.Y1493* | Nonsense Mutation (SNP) | VAF 33/239 reads (14%) | catalogued as COSV54557461; called by muse, mutect2, varscan2
- TLR1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58304127; called by muse, mutect2, varscan2
- TLR8 | c.2755G>T p.E919* (on ENST00000218032 / NM_138636.5; = p.E937* on NM_016610.4) | Nonsense Mutation (SNP) | VAF 47/66 reads (71%) | catalogued as COSV54318644; called by muse, mutect2, varscan2
- TMEM187 | c.21G>C p.Q7H | Missense Mutation (SNP) | VAF 113/147 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.366); catalogued as rs782003678; called by muse, mutect2, varscan2
- TNFRSF18 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs371585133; called by muse, mutect2, varscan2
- TNN | c.2191G>T p.V731L | Missense Mutation (SNP) | VAF 330/649 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99512395; called by muse, mutect2, varscan2
- TOGARAM2 | c.2684G>A p.S895N | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV65422954; called by muse, mutect2, varscan2
- TOM1L1 | c.944A>T p.Q315L | Missense Mutation (SNP) | VAF 158/257 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV61948008; called by muse, mutect2, varscan2
- TPR | c.5650C>T p.Q1884* | Nonsense Mutation (SNP) | VAF 46/159 reads (29%) | catalogued as COSV66601318; called by muse, mutect2, varscan2
- TRAPPC10 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 190/310 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs375606142; called by muse, mutect2, varscan2
- TRHDE | c.2912C>A p.T971N | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53871475; called by muse, mutect2, varscan2
- TRIM42 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV53886889; called by muse, mutect2, varscan2
- TRPA1 | c.3296G>A p.R1099K | Missense Mutation (SNP) | VAF 215/633 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs778891599, COSV51573181; called by muse, mutect2, varscan2
- TRPS1 | c.1268C>G p.S423C (on ENST00000220888 / NM_001330599.2; = p.S436C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV55246908; called by muse, mutect2, varscan2
- TSPAN33 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.821); catalogued as COSV56825600, COSV56827592; called by muse, mutect2, varscan2
- TTC27 | c.1692G>T p.W564C | Missense Mutation (SNP) | VAF 129/280 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV58649237; called by muse, mutect2, varscan2
- TTC32 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1238765222; called by muse, mutect2, varscan2
- TTLL13P | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 116/304 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV60040577; called by muse, mutect2, varscan2
- TTLL5 | c.1661G>C p.R554P | Missense Mutation (SNP) | VAF 252/332 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV54038765; called by muse, mutect2, varscan2
- TTN | c.69139C>A p.R23047S (on ENST00000591111; = p.R15623S on NM_003319.4) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | PolyPhen probably damaging (0.999); catalogued as COSV59998073; called by muse, mutect2, varscan2
- TTN | c.7021G>T p.D2341Y (on ENST00000591111; = p.D2295Y on NM_003319.4) | Missense Mutation (SNP) | VAF 118/339 reads (35%) | PolyPhen possibly damaging (0.891); catalogued as rs781736462, COSV60107188; called by muse, mutect2, varscan2
- TTYH2 | c.1539G>A p.M513I | Missense Mutation (SNP) | VAF 143/185 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs753950074, COSV53909810; called by muse, mutect2, varscan2
- TUB | c.537G>T p.Q179H (on ENST00000299506 / NM_177972.3; = p.Q234H on NM_003320.4) | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1451765039, COSV55109417; called by muse, mutect2, varscan2
- UBAP2L | c.2945C>T p.S982L | Missense Mutation (SNP) | VAF 163/339 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs753275698; called by muse, mutect2, varscan2
- UBQLNL | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs1356861492; called by muse, mutect2, varscan2
- UGT3A2 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV99236583, COSV99236861; called by muse, mutect2, varscan2
- UNC5C | c.2024C>A p.T675N | Missense Mutation (SNP) | VAF 139/358 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs374566244; called by muse, mutect2, varscan2
- UNC5D | c.1994C>A p.A665E | Missense Mutation (SNP) | VAF 139/267 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs781317548, COSV54766380, COSV54783476, COSV54804437; called by mutect2, varscan2
- USH1G | c.1201A>G p.M401V | Missense Mutation (SNP) | VAF 307/379 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs868106772; called by muse, mutect2, varscan2
- USP10 | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.908); catalogued as rs745488756; called by muse, mutect2, varscan2
- USP29 | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as rs1011633218, COSV99518666; called by muse, mutect2, varscan2
- VIT | c.866-2A>G p.X289_splice (on ENST00000389975 / NM_001177969.1; = p.X304_splice on NM_053276.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 38/244 reads (16%) | catalogued as rs1252932787; called by muse, mutect2, varscan2
- WDR70 | c.1068A>G p.I356M | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1475014927; called by muse, mutect2, varscan2
- WIZ | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs751690140; called by muse, mutect2, varscan2
- XCR1 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs1442595346; called by muse, mutect2, varscan2
- XIRP2 | c.9271G>T p.E3091* (on ENST00000628543; = p.E3266* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 57/168 reads (34%) | catalogued as COSV54680331; called by muse, mutect2, varscan2
- XPR1 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.262); catalogued as COSV62560291; called by muse, mutect2, varscan2
- XRN1 | c.4654del p.A1552Qfs*4 | Frame Shift Del (DEL) | VAF 47/306 reads (15%) | catalogued as COSV53808801; called by mutect2*, pindel, varscan2*
- ZDBF2 | c.2104A>G p.S702G | Missense Mutation (SNP) | VAF 92/185 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as rs1279703632; called by muse, mutect2, varscan2
- ZDHHC24 | c.204C>G p.N68K | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1201782309; called by muse, mutect2, varscan2
- ZDHHC8 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1294362218; called by muse, varscan2
- ZFAND1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 80/364 reads (22%) | catalogued as rs540661193; called by muse, mutect2, varscan2
- ZFHX4 | c.8032C>G p.P2678A | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV50521688; called by muse, mutect2, varscan2
- ZIC4 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 127/371 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268213; called by muse, mutect2, varscan2
- ZIC5 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1346762601; called by muse, mutect2, varscan2
- ZNF124 | c.336C>A p.D112E | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1553334397; called by muse, mutect2, varscan2
- ZNF250 | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99480626; called by muse, mutect2, varscan2
- ZNF347 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 110/168 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61967691; called by muse, varscan2
- ZNF415 | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99701842; called by muse, mutect2, varscan2
- ZNF45 | c.1659G>C p.E553D | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99524195; called by muse, mutect2, varscan2
- ZNF460 | c.356A>G p.H119R | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1352784246; called by muse, mutect2, varscan2
- ZNF468 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 136/227 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54695911; called by muse, mutect2, varscan2
- ZNF506 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs369665225, COSV71354205, COSV71354875; called by muse, mutect2, varscan2
- ZNF541 | c.2885G>T p.G962V | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.925); catalogued as rs1379538998; called by muse, mutect2, varscan2
- ZNF574 | c.2543A>G p.H848R | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs766809497; called by muse, mutect2, varscan2
- ZNF580 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1021499470; called by muse, mutect2, varscan2
- ZNF724 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV69030817; called by muse, mutect2, varscan2
- ZNF77 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779727618; called by muse, mutect2, varscan2
- ZNF787 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99555764; called by muse, mutect2, varscan2
- ZNF80 | c.467C>A p.T156N | Missense Mutation (SNP) | VAF 193/410 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV100352105; called by muse, mutect2, varscan2
- ZNF804B | c.2427A>T p.K809N | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV60851798, COSV60865524; called by muse, mutect2, varscan2
- ZNF804B | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs768312984, COSV60859792; called by muse, mutect2
- ZNF875 | c.186G>C p.M62I | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60990279; called by muse, mutect2, varscan2
- ZSCAN12 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as rs762954476; called by muse, mutect2, varscan2
- A2ML1 | c.660G>C p.K220N | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- A2ML1 | c.2761A>G p.K921E | Missense Mutation (SNP) | VAF 176/400 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- AARS2 | c.1189-1G>T p.X397_splice | Splice Site (SNP) | VAF 125/486 reads (26%) | called by muse, mutect2, varscan2
- AASS | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 185/512 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AATK | c.1897G>T p.A633S (on ENST00000326724 / NM_001080395.3; = p.A530S on NM_004920.2) | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.35); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ABCA10 | c.2980T>G p.S994A | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT tolerated (0.54); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABCA13 | c.3343A>T p.S1115C | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ABCA2 | c.3070G>C p.D1024H (on ENST00000614293; = p.D994H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/160 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ABCA4 | c.6531C>A p.D2177E | Missense Mutation (SNP) | VAF 246/349 reads (70%) | SIFT tolerated (0.95); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCB1 | c.3489+1G>T p.X1163_splice | Splice Site (SNP) | VAF 70/397 reads (18%) | called by muse, mutect2, varscan2
- ABCC1 | c.1515G>T p.M505I | Missense Mutation (SNP) | VAF 115/171 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ABCC11 | c.3233T>A p.V1078D | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCC11 | c.604G>T p.G202* | Nonsense Mutation (SNP) | VAF 105/260 reads (40%) | called by muse, mutect2, varscan2
- ABCC12 | c.2559G>T p.W853C | Missense Mutation (SNP) | VAF 265/581 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC2 | c.3454G>T p.D1152Y | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ABCD2 | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCG4 | c.155A>C p.H52P | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ABCG8 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 270/475 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ABLIM3 | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- AC004593.2 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AC026316.4 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 50/202 reads (25%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- AC100868.1 | c.553A>T p.S185C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- AC245033.1 | c.1589G>T p.R530I | Missense Mutation (SNP) | VAF 234/618 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ACKR1 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACO1 | c.1925A>T p.Y642F | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACSM1 | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 167/262 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN1 | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 193/237 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ACTRT1 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 88/113 reads (78%) | SIFT tolerated (0.9); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADAM15 | c.1415A>T p.Q472L | Missense Mutation (SNP) | VAF 128/236 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ADAM23 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM33 | c.2330T>C p.L777P | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAM9 | c.1888A>G p.R630G | Missense Mutation (SNP) | VAF 97/174 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ADAMTS12 | c.963C>A p.F321L | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS14 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS16 | c.1741G>T p.G581C | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS4 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADAMTS8 | c.1457G>C p.C486S | Missense Mutation (SNP) | VAF 69/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAP1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ADAP1 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ADGRA3 | c.906C>A p.C302* | Nonsense Mutation (SNP) | VAF 81/208 reads (39%) | called by muse, mutect2, varscan2
- ADGRB2 | c.2239G>T p.G747C | Missense Mutation (SNP) | VAF 69/81 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ADGRG4 | c.2350C>A p.P784T | Missense Mutation (SNP) | VAF 79/99 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ADGRG7 | c.74del p.L25Wfs*9 | Frame Shift Del (DEL) | VAF 85/301 reads (28%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.4354C>A p.Q1452K (on ENST00000506720 / NM_001322402.2; = p.Q1341K on NM_015236.6) | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ADGRL4 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ADH1A | c.173T>C p.M58T | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ADH1C | c.943T>C p.W315R | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ADH1C | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 111/216 reads (51%) | SIFT tolerated (0.86); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADORA3 | c.927G>T p.L309F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ADRA2C | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- AFG1L | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- AFP | c.47C>G p.T16S | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AGL | c.4415A>T p.E1472V | Missense Mutation (SNP) | VAF 98/190 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by mutect2, varscan2
- AGTR1 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AIM2 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- AJAP1 | c.947A>T p.N316I | Missense Mutation (SNP) | VAF 92/123 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- AKAP9 | c.6438A>C p.L2146F (on ENST00000359028; = p.L2114F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALK | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ALOX5 | c.980A>T p.Q327L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALPK3 | c.2935G>T p.G979W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ALPP | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALX3 | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- AMN1 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMPD1 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 128/567 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMPD2 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- AMY2B | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 107/216 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.10694A>T p.E3565V | Missense Mutation (SNP) | VAF 80/407 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, varscan2
- ANKFN1 | c.3864G>T p.M1288I (on ENST00000653862; = p.M1141I on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD18A | c.2899A>T p.T967S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ANKRD27 | c.1116+2T>A p.X372_splice | Splice Site (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- ANKRD28 | c.1432G>T p.A478S | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ANKRD33B | c.1045C>G p.R349G | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ANKRD36 | c.1939G>T p.V647L | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ANKRD45 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKS1B | c.302G>T p.W101L | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANLN | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA10 | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANXA6 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- AP1M1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP2A1 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBA1 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- APEH | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.466A>T p.I156F | Missense Mutation (SNP) | VAF 153/668 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOB | c.227_237+7del p.X76_splice | Splice Site (DEL) | VAF 131/669 reads (20%) | called by mutect2, pindel, varscan2
- APPL2 | c.544T>A p.Y182N | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARC | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARFGEF2 | c.4758A>G p.Q1586= | Splice Region (SNP) | VAF 124/336 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.509A>T p.Q170L | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ARHGAP23 | c.4181C>A p.P1394H | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ARHGEF17 | c.5901G>T p.Q1967H | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARMC4 | c.1760G>C p.C587S | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARMH4 | c.1992G>T p.Q664H | Missense Mutation (SNP) | VAF 142/247 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARNT2 | c.613T>A p.S205T | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ARNT2 | c.901G>C p.A301P | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARPIN | c.672+7A>G | Splice Region (SNP) | VAF 64/187 reads (34%) | called by muse, mutect2, varscan2
- ARRB1 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ARVCF | c.1369del p.D457Tfs*21 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- ASCL4 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ASIC5 | c.1236-2A>G p.X412_splice | Splice Site (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- ASPM | c.10402A>G p.M3468V | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ASPM | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG2A | c.926A>G p.H309R | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B2 | c.2885-2A>C p.X962_splice (on ENST00000352432; = p.X928_splice on NM_001683.5) | Splice Site (SNP) | VAF 140/404 reads (35%) | called by muse, mutect2, varscan2
- ATP6V0C | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ATP6V1A | c.1700G>A p.W567* | Nonsense Mutation (SNP) | VAF 97/293 reads (33%) | called by muse, mutect2, varscan2
- ATP6V1A | c.1701G>T p.W567C | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AUTS2 | c.2753A>G p.E918G | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AXDND1 | c.2594A>G p.K865R | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BACH1 | c.1359C>A p.F453L | Missense Mutation (SNP) | VAF 93/153 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BACH2 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 175/452 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BASP1 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- BBS4 | c.1435A>G p.R479G | Missense Mutation (SNP) | VAF 178/467 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAT2 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 87/136 reads (64%) | SIFT tolerated (0.46); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BCDIN3D | c.13A>T p.T5S | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BCR | c.3656G>C p.S1219T | Missense Mutation (SNP) | VAF 146/384 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- BDP1 | c.5434G>T p.D1812Y | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- BFSP2 | c.554C>A p.A185E | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- BICC1 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- BICD1 | c.2294A>T p.Q765L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BMPER | c.730G>C p.V244L | Missense Mutation (SNP) | VAF 85/401 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BNC1 | c.2038G>T p.A680S | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BOC | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 58/195 reads (30%) | called by muse, mutect2, varscan2
- BPIFB2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- BRINP1 | c.1029G>C p.K343N | Missense Mutation (SNP) | VAF 270/513 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- BTLA | c.631A>G p.S211G | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf42 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- C1QTNF5 | c.43_53del p.G15Tfs*102 | Frame Shift Del (DEL) | VAF 72/346 reads (21%) | called by mutect2, pindel, varscan2
- C1orf56 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- C2CD2 | c.1449T>A p.N483K | Missense Mutation (SNP) | VAF 198/292 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C2CD4D | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 63/284 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3orf20 | c.926T>A p.M309K | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2
- C6orf132 | c.3328del p.A1110Rfs*58 | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | called by pindel, varscan2
- C6orf47 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 78/103 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- C8G | c.53C>G p.S18W | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- CA12 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 176/464 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, varscan2
- CACNA1G | c.3616G>T p.G1206W | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CACNA2D1 | c.961G>C p.A321P | Missense Mutation (SNP) | VAF 120/302 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CACNA2D1 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 131/566 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CALB1 | c.504C>A p.A168= | Splice Region (SNP) | VAF 52/273 reads (19%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAMSAP1 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN7 | c.500A>T p.K167M | Missense Mutation (SNP) | VAF 140/391 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAPSL | c.62C>A p.T21K | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CARD9 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CARMIL1 | c.130A>C p.K44Q | Missense Mutation (SNP) | VAF 108/155 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CBWD6 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.085); called by mutect2, varscan2
- CBWD6 | c.932T>A p.M311K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by mutect2, varscan2
- CBY2 | c.262C>A p.H88N | Missense Mutation (SNP) | VAF 74/111 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CCDC14 | c.815G>T p.C272F (on ENST00000488653; = p.C224F on NM_022757.5) | Missense Mutation (SNP) | VAF 116/338 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CCDC149 | c.93T>G p.S31R | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 71/358 reads (20%) | called by muse, mutect2, varscan2
- CCDC96 | c.980G>T p.W327L | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCER1 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCM2L | c.1174A>T p.T392S (on ENST00000452892 / NM_001365692.1; = p.A370= on NM_080625.4) | Missense Mutation (SNP) | VAF 96/371 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CCNE2 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCR2 | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- CCT4 | c.1492-2A>T p.X498_splice | Splice Site (SNP) | VAF 56/242 reads (23%) | called by muse, varscan2
- CD1D | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDC5L | c.1810G>T p.G604W | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- CDH13 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CDH8 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 165/429 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CDK5RAP2 | c.5309G>A p.G1770D | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CEBPB | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 249/610 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CELSR3 | c.3326G>T p.G1109V | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CENPJ | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 205/586 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CENPP | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CFAP100 | c.1574C>A p.P525H | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CFAP58 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, varscan2
- CFAP61 | c.2874C>A p.D958E | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP99 | c.413T>A p.L138H | Missense Mutation (SNP) | VAF 135/258 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CFHR3 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 78/300 reads (26%) | called by muse, mutect2, varscan2
- CFHR5 | c.1639G>C p.A547P | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CHD4 | c.4390A>T p.T1464S (on ENST00000357008 / NM_001363606.2; = p.T1477S on NM_001273.5) | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHD7 | c.5305G>T p.A1769S | Missense Mutation (SNP) | VAF 91/165 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CHEK1 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 155/372 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CHERP | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHIA | c.813C>A p.F271L (on ENST00000343320; = p.F163L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CHRM2 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 167/477 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CHST3 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 136/355 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CIC | c.4805C>T p.S1602F | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CILP | c.2258T>C p.F753S | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CISD1 | c.227G>T p.R76M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CIT | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CLASRP | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CLCA2 | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 75/117 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCA4 | c.1372T>G p.F458V | Missense Mutation (SNP) | VAF 113/160 reads (71%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CLCN7 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 126/180 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CLDN18 | c.647A>C p.H216P | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, varscan2
- CLEC16A | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 132/197 reads (67%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CLEC6A | c.491G>C p.W164S | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLP1 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CNGB1 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CNTNAP4 | c.1191dup p.F398Ifs*6 | Frame Shift Ins (INS) | VAF 87/229 reads (38%) | called by mutect2, pindel, varscan2
- COL12A1 | c.904T>G p.F302V | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL14A1 | c.686C>A p.P229Q | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL15A1 | c.3875C>A p.S1292Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL16A1 | c.3607C>A p.P1203T | Missense Mutation (SNP) | VAF 105/137 reads (77%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- COL19A1 | c.641G>C p.R214P | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL19A1 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- COL19A1 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- COL1A2 | c.2968G>C p.A990P | Missense Mutation (SNP) | VAF 227/815 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- COL2A1 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL3A1 | c.3641del p.G1214Afs*22 | Frame Shift Del (DEL) | VAF 57/198 reads (29%) | called by mutect2, pindel, varscan2
- COL4A5 | c.1663G>T p.G555* | Nonsense Mutation (SNP) | VAF 178/217 reads (82%) | called by muse, mutect2, varscan2
- COMMD1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 22/329 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- COQ5 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CORIN | c.2400A>C p.K800N | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CORO7 | c.1712T>C p.L571P | Missense Mutation (SNP) | VAF 127/173 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPB2 | c.575T>A p.L192* | Nonsense Mutation (SNP) | VAF 47/72 reads (65%) | called by muse, mutect2, varscan2
- CPED1 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPSF3 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPSF3 | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 181/311 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CPZ | c.497-7C>A | Splice Region (SNP) | VAF 142/305 reads (47%) | called by muse, mutect2, varscan2
- CPZ | c.1058G>T p.W353L (on ENST00000360986 / NM_001014447.3; = p.W342L on NM_003652.3) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CREB3L1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CREG2 | c.544del p.V182Wfs*4 | Frame Shift Del (DEL) | VAF 75/246 reads (30%) | called by mutect2, varscan2
- CRHR2 | c.989C>G p.P330R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRISPLD1 | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRLF2 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CSN3 | c.431C>A p.P144Q | Missense Mutation (SNP) | VAF 85/392 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CSNK1E | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CSTF1 | c.1125del p.I376Sfs*28 | Frame Shift Del (DEL) | VAF 124/422 reads (29%) | called by mutect2, pindel, varscan2
- CSTL1 | c.331-2A>C p.X111_splice | Splice Site (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- CTNNA3 | c.474dup p.E159* | Frame Shift Ins (INS) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- CTNNAL1 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTSA | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUBN | c.9366G>T p.K3122N | Missense Mutation (SNP) | VAF 319/692 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CUBN | c.2944C>T p.H982Y | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CUL7 | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 74/393 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CWC22 | c.2395A>G p.R799G | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CXXC4 | c.709del p.S237Pfs*6 | Frame Shift Del (DEL) | VAF 36/101 reads (36%) | called by mutect2, pindel, varscan2
- CXorf66 | c.838A>T p.R280W | Missense Mutation (SNP) | VAF 73/103 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CYB5R3 | c.492del p.K164Nfs*9 | Frame Shift Del (DEL) | VAF 86/139 reads (62%) | called by mutect2, varscan2*
- CYB5R3 | c.491del p.K164Sfs*9 | Frame Shift Del (DEL) | VAF 66/181 reads (36%) | called by mutect2*, pindel
- CYP3A7 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 148/462 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- CYP4B1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAAM2 | c.1846-1G>T p.X616_splice | Splice Site (SNP) | VAF 34/173 reads (20%) | called by muse, mutect2, varscan2
- DAB2 | c.1440G>T p.Q480H | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- DACH1 | c.1762A>T p.S588C (on ENST00000619232 / NM_001366712.1; = p.S334C on NM_004392.6) | Missense Mutation (SNP) | VAF 103/184 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DCAF8L2 | c.1894T>A p.*632Rext*? | Nonstop Mutation (SNP) | VAF 7/8 reads (88%) | called by muse, mutect2, varscan2
- DCST1 | c.1963C>G p.P655A | Missense Mutation (SNP) | VAF 210/402 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCX | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 82/104 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- DDB1 | c.2185G>T p.V729L | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- DDB1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX39A | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DEFB115 | c.37A>C p.I13L | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DENND2A | c.1084C>G p.R362G | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- DENND4B | c.3226A>G p.I1076V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, varscan2
- DENND4B | c.3164G>T p.R1055L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, varscan2
- DENND4B | c.659dup p.E221Gfs*5 | Frame Shift Ins (INS) | VAF 19/67 reads (28%) | called by pindel, varscan2
- DEPDC5 | c.3716A>T p.Q1239L (on ENST00000400246; = p.Q1308L on NM_014662.5) | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKB | c.841A>T p.T281S | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKZ | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DHX57 | c.573-2A>T p.X191_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- DIP2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 142/256 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DKK1 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMBT1 | c.4996T>G p.Y1666D (on ENST00000338354 / NM_001377530.1; = p.Y909D on NM_004406.3) | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- DMRT2 | c.821T>C p.M274T | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DMXL2 | c.4780C>G p.Q1594E | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DNAAF2 | c.1562T>G p.L521W | Missense Mutation (SNP) | VAF 102/148 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DNAI3 | c.858-1G>T p.X286_splice | Splice Site (SNP) | VAF 47/64 reads (73%) | called by muse, mutect2, varscan2
- DOCK1 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK1 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- DOCK10 | c.3010C>G p.H1004D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DOP1B | c.4586A>T p.Y1529F | Missense Mutation (SNP) | VAF 128/224 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DPP10 | c.1531+1G>T p.X511_splice | Splice Site (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- DPY19L2 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- DPY19L2 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 101/210 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, varscan2
- DPYD | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 129/221 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DPYS | c.1192G>T p.G398* | Nonsense Mutation (SNP) | VAF 61/422 reads (14%) | called by muse, mutect2, varscan2
- DRD5 | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DSG4 | c.2572C>A p.H858N | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DSPP | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 135/299 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
1,480 further variants in this file (767 protein-altering or splice-affecting, 417 silent, 296 other) are not listed here.
